Surgical pathology report (de-identified scan), TCGA case TCGA-A6-2672, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-2672-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Right colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Colon cancer

GROSS DESCRIPTION

Received fresh, subsequently fixed in formalin labelled "right colon" which is partially covered with pink-tan smooth glistening serosa and yellow lobular fat. The specimen shows a 6.5 x 0.7 cm appendix and the specimen is predominately covered with abundant yellow lobular fat. The specimen is opened and has a 6.5 cm portion of small bowel and 26 cm of cecum and colon. The specimen shows a large ectophytic mass which is 7.0 x 5.5 x 1.2 cm. This is located 6.5 cm from the distal margin. The cut surface of the tumor shows gross invasion into the muscularis propria, however, showing possible invasion into the fat. This comes within 6.5 cm of the radial margin. No other discrete gross lesions are identified. The average circumference of the small bowel is 4.0 cm and the average circumference of the cecum and colon is 7.0 cm. Representative sections of the specimen are submitted as follows: BLOCK SUMMARY: 1 - representative luminal margins and ileocecal valve; 2 - representative section of appendix with proximal end inked; 3-5 - representative sections of tumor to normal and fat; 6 - radial margin with lymph node at radial margin; 7-8 - nine possible lymph nodes; 9 - six possible lymph nodes; 10 - three possible lymph nodes; 11 - three possible lymph nodes; 12 - one possible lymph node from near radial margin; 13-14 - one lymph node bisected. RS-14.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma.
Histologic grade: Moderately-differentiated.
Primary tumor: pT3 (carcinoma penetrates through the muscularis propria, into the subserosal fat).
Proximal margin: Negative.
Distal margin: Negative.
Circumferential (radial) margin: Negative.
Vascular invasion: Probable.
Regional lymph nodes (pN): One of twenty-nine lymph nodes with metastatic carcinoma .
Non-lymph node pericolic tumor: Not identified.
Other findings: Appendix with serosal fat necrosis and otherwise unremarkable; small bowel unremarkable.

5

DIAGNOSIS

Right Colon with appendix, small bowel, right hemicolectomy:
Adenocarcinoma, moderately differentiated, with invasion through the muscularis propria, into the subserosal fat (pT3).
Margins of excision negative.
One of twenty-nine lymph nodes with metastatic carcinoma .

Source: NCI Genomic Data Commons file abb68cde-eaee-43f4-a4ca-665b11bd68a7 (TCGA-A6-2672.8405A327-719D-4C6D-99F4-A58306C8FDC4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).